Somatic mutation profile of tumor specimen 0DX7FR from CCDI case PBCPXM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.1 years (1,861 days).
Specimen 0DX7FR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c30df387-86f9-4952-969a-50453a594f38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7ET (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8272a01-9f4f-4738-ad4c-f1306f40f0fc

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 5, Silent 3, 3'UTR 3, 5'UTR 2, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as rs770635604; called by muse, mutect2, varscan2
- CCDC80 | c.2172G>A p.K724= | Splice Region (SNP) | VAF 114/305 reads (37%) | catalogued as rs763561315, COSV99244838; called by muse, mutect2, varscan2
- DCLK2 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 223/434 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56200418; called by muse, mutect2, varscan2
- GOLGB1 | c.6596A>G p.D2199G | Missense Mutation (SNP) | VAF 88/448 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756313386; called by muse, mutect2, varscan2
- PKHD1 | c.6116T>C p.L2039P | Missense Mutation (SNP) | VAF 170/443 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777228780, CM149119; called by muse, mutect2, varscan2
- PTPN5 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV100080052; called by muse, mutect2, varscan2
- APLN | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.103); called by muse, mutect2
- CACNA2D1 | c.2008C>A p.L670M (on ENST00000356253 / NM_001366867.1; = p.L658M on NM_000722.4) | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DIPK2A | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJB4 | c.640A>C p.I214L | Missense Mutation (SNP) | VAF 151/349 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- FRMPD2 | c.1230G>T p.W410C | Missense Mutation (SNP) | VAF 162/470 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIDINS220 | c.2108C>A p.A703D | Missense Mutation (SNP) | VAF 157/232 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- LRRC15 | c.766C>G p.H256D | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LSS | c.1533G>T p.L511F | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NEMP1 | c.973A>T p.T325S (on ENST00000300128 / NM_001130963.2; = p.T252S on NM_015257.3) | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- NOSIP | c.259-3C>G | Splice Region (SNP) | VAF 271/319 reads (85%) | called by muse, mutect2, varscan2
- TRNP1 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TTC4 | c.1023_1042del p.A342Gfs*58 | Frame Shift Del (DEL) | VAF 48/256 reads (19%) | called by mutect2, varscan2
- ZNF618 | c.1627A>T p.S543C (on ENST00000374126 / NM_001318042.2; = p.S450C on NM_133374.2) | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRLS1 | c.243C>T p.A81= | Silent (SNP) | VAF 77/182 reads (42%) | called by muse, mutect2, varscan2
- SLC2A3 | c.30G>T p.L10= | Silent (SNP) | VAF 100/386 reads (26%) | called by muse, mutect2, varscan2
- TNRC6B | c.33G>A p.Q11= | Silent (SNP) | VAF 72/264 reads (27%) | called by muse, mutect2, varscan2
- CAPN1 | c.591-57C>T | Intron (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- CLASRP | c.1708-64G>T | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- COL6A3 | c.9328+58C>A | Intron (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- LUC7L | c.975-77G>T | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- MECOM | c.-52del | 5'UTR (DEL) | VAF 6/61 reads (10%) | called by mutect2, varscan2
- MISP | c.*6G>C | 3'UTR (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- PLS3 | c.*38G>T | 3'UTR (SNP) | VAF 44/49 reads (90%) | called by muse, mutect2, varscan2
- SDK2 | c.*60C>T | 3'UTR (SNP) | VAF 23/152 reads (15%) | catalogued as rs1263952827; called by muse, mutect2, varscan2
- SEC16B | c.-43G>T | 5'UTR (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- STAT3 | c.1281+85A>G | Intron (SNP) | VAF 30/111 reads (27%) | catalogued as rs1160992039; called by muse, mutect2, varscan2
